Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXI-01A (Primary Tumor).

SPEC #: Status: Obtained: Received:

CLINICAL HISTORY:
233.1

SPECIMEN/PROCEDURE:
1. CERVIX - BIOPSY

IMPRESSION:

CERVICAL BIOPSY AT 6 O'CLOCK:

- . Squamous cell carcinoma, large cell, non-keratinizing with stromal invasion, grade II.
- . No vascular space invasion is identified.

Dictated by:
Entered:

GROSS DESCRIPTION:

This case is part of the

Received in formalin labeled " and with patient name are 2 irregular unoriented portions of deep red to pink-tan glistening tissue, 0.8 x 0.7 x 0.3 cm and 1.5 x 0.7 x 0.4 cm. Each portion of tissue, serially sectioned. Specimen is entirely submitted in one cassette.

Dictated by:
Entered:

CPT Codes:
CERVICAL BIOPSY/88305

ICD9 Codes:
180.9, 233.1
Resident Physician:

ICD-0.3
(carcinoma), squamous cell, large cell, non-keratinizing NOS 8072/3
Site Cervix NOS 053.9
7/26/14

I have personally reviewed the material (specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 49f13908-064e-4584-9fba-921fa3edac39 (TCGA-ZJ-AAXI.D446A3B4-E137-4A6C-9C17-FEED0163DAED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).